Somatic mutation profile of tumor specimen TCGA-VQ-A922-01A (aliquot TCGA-VQ-A922-01A-11D-A410-08) from TCGA case TCGA-VQ-A922, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 70.4 years (25,700 days).
Specimen TCGA-VQ-A922-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc0b4a68-e0f8-482b-b9d8-bd9dec13971a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A922-10A (Blood Derived Normal), aliquot TCGA-VQ-A922-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08211be2-7dd3-4c8f-b2cb-feb5d11bb8f0

The open-access MAF lists 151 somatic variants for this specimen: 113 protein-altering or splice-affecting, 32 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 32, Nonsense Mutation 6, Intron 3, RNA 2, Frame Shift Ins 2, 5'Flank 1, In Frame Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6 | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 54/213 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV54704910, COSV54705322; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 24/40 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2528T>G p.L843R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55944976; called by muse, mutect2, varscan2
- ABCG5 | c.1784C>T p.T595I | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99571238; called by muse, mutect2
- ADAM21 | c.1065C>A p.F355L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV99961058; called by muse, mutect2, varscan2
- ADAMTS1 | c.1813T>C p.Y605H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99536177; called by muse, mutect2, varscan2
- ADAMTS15 | c.2591T>C p.V864A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100143410; called by muse, mutect2, varscan2
- ADAMTS16 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs762936790, COSV99941383; called by muse, mutect2
- ADCY8 | c.2490C>A p.C830* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99652511; called by muse, mutect2, varscan2
- ANKRD30A | c.2832T>A p.H944Q (on ENST00000611781; = p.H888Q on NM_052997.2) | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV100653612; called by muse, mutect2
- AP002512.3 | c.344T>G p.F115C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV99687971; called by muse, mutect2
- ARFGEF2 | c.1213G>C p.V405L | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV100904275; called by muse, mutect2
- ARID3B | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100654650; called by muse, mutect2
- C5orf22 | c.557A>T p.D186V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100323498; called by muse, mutect2, varscan2
- CASP14 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.556); catalogued as COSV99693041; called by muse, mutect2, varscan2
- CD1E | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV100937010, COSV63770217; called by muse, mutect2, varscan2
- CDC25A | c.1064A>C p.Q355P | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100207493; called by muse, mutect2
- CDH11 | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV51759327, COSV51759358, COSV51764779; called by muse, mutect2
- CDK20 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100308095; called by muse, mutect2, varscan2
- CDK5 | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV99876988; called by muse, mutect2, varscan2
- CEP192 | c.7048-2A>C p.X2350_splice | Splice Site (SNP) | VAF 5/84 reads (6%) | catalogued as COSV100381325, COSV58070521; called by muse, mutect2
- CEP290 | c.3886G>A p.D1296N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV100468807, COSV58350208; called by muse, mutect2
- CKM | c.749T>G p.F250C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99488337; called by muse, mutect2, varscan2
- COL11A1 | c.5362T>C p.F1788L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV100616746, COSV62177757; called by muse, mutect2, varscan2
- COL12A1 | c.3281A>C p.K1094T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.307); catalogued as COSV100486037; called by muse, mutect2, varscan2
- CUBN | c.4306T>G p.F1436V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100912766; called by muse, mutect2, varscan2
- DDR1 | c.2217C>G p.S739R (on ENST00000324771; = p.S702R on NM_001954.4) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1328129352, COSV100241579; called by muse, mutect2
- DDX42 | c.2566G>A p.G856S | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV100834938; called by muse, mutect2, varscan2
- DLG5 | c.4320C>T p.S1440= | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100967517; called by muse, mutect2, varscan2
- DSCAM | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as rs761258332, COSV101260301; called by muse, mutect2, varscan2
- DUSP5 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.122); catalogued as COSV100851900; called by muse, mutect2, varscan2
- EPHA5 | c.395T>G p.F132C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56645847, COSV99900635, COSV99902166; called by muse, mutect2, varscan2
- ESS2 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52816371, COSV99350919; called by muse, mutect2
- FGFR2 | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100336320; called by muse, mutect2, varscan2
- FLNC | c.3683T>C p.I1228T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV100368162; called by muse, mutect2
- FOSB | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs780157288, COSV100798771, COSV100798802; called by muse, mutect2, varscan2
- GAB4 | c.1469T>G p.L490R | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV101271993, COSV68755240; called by muse, mutect2
- GANAB | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1168214826, COSV60463006; called by muse, mutect2, varscan2
- GDPD1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV52383970; called by muse, mutect2, varscan2
- GFRA1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62609593; called by muse, mutect2, varscan2
- GLI2 | c.3704C>T p.P1235L (on ENST00000361492 / NM_001374353.1; = p.P1252L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV100083306; called by muse, mutect2, varscan2
- GNAS | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV100006625; called by muse, mutect2, varscan2
- GNS | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99253822; called by muse, mutect2
- GPC5 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100994187; called by muse, mutect2, varscan2
- GRK1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs762974373, COSV100175448, COSV59552976; called by muse, mutect2, varscan2
- HYAL4 | c.1070T>A p.F357Y | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as COSV99772252; called by muse, mutect2, varscan2
- INTU | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs373140548; called by muse, mutect2, varscan2
- IQCC | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.135); catalogued as COSV99356601; called by muse, mutect2
- ITPKC | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV99648781; called by muse, mutect2
- LLGL2 | c.874A>G p.R292G | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs760690036, COSV99389770; called by muse, mutect2
- LRIG2 | c.2718T>A p.Y906* | Nonsense Mutation (SNP) | VAF 18/179 reads (10%) | catalogued as COSV100743389; called by muse, mutect2
- MIA3 | c.4552C>T p.Q1518* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV60513557; called by muse, mutect2, varscan2
- MSANTD2 | c.860T>C p.I287T (on ENST00000374979 / NM_001308027.2; = p.I235T on NM_024631.4) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99515572; called by muse, mutect2, varscan2
- MYH14 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1215986558, CM1513072, COSV99222829; called by muse, mutect2, varscan2
- MYH7B | c.2296T>G p.F766V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99482814; called by muse, mutect2, varscan2
- NDST4 | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV52116304, COSV99996607; called by muse, mutect2, varscan2
- NECAP1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100331590; called by muse, varscan2
- NETO1 | c.1267T>G p.S423A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV100198834; called by muse, mutect2, varscan2
- NFIL3 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99906913; called by muse, mutect2
- NOVA1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57473964; called by muse, mutect2, varscan2
- NRXN3 | c.868T>C p.W290R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.987); catalogued as rs771218621, COSV100204297; called by muse, mutect2, varscan2
- OLFM3 | c.404G>A p.R135Q (on ENST00000338858 / NM_001288821.1; = p.R115Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.988); catalogued as rs558293456, COSV58804736; called by muse, mutect2, varscan2
- OR10J3 | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100171748; called by muse, mutect2
- OR2G6 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1311283685, COSV58575046; called by muse, mutect2, varscan2
- OR2M3 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 186/302 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV101513439; called by muse, mutect2, varscan2
- OR8D1 | c.767C>G p.T256S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.665); catalogued as COSV100766651, COSV63441643; called by muse, mutect2, varscan2
- PARD3 | c.3400C>T p.R1134W | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs138980029; called by muse, mutect2
- PBOV1 | c.234T>G p.H78Q | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV99293658; called by muse, mutect2, varscan2
- POU6F1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100374823; called by muse, mutect2
- POU6F1 | c.1168G>C p.A390P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV100374826; called by muse, mutect2
- PRKDC | c.8480C>G p.S2827C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV100040813; called by muse, mutect2, varscan2
- PRPS1L1 | c.845A>T p.K282M | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV101552935; called by muse, mutect2, varscan2
- PSMC4 | c.598dup p.R200Pfs*43 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs765768285; called by mutect2, varscan2
- PSME4 | c.3193A>G p.M1065V | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs757290403, COSV101122515; called by muse, mutect2
- PTPRD | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.092); catalogued as COSV100644915; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99770109; called by muse, mutect2
- RHOB | c.355A>G p.K119E | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV99695272; called by muse, mutect2
- RP1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs367600337, COSV55109473, COSV55128616; called by muse, mutect2
- SCFD2 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101189382; called by muse, mutect2
- SDK2 | c.5553A>T p.K1851N | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV101167700; called by muse, mutect2
- SH2D5 | c.1222C>T p.R408W (on ENST00000444387 / NM_001103161.2; = p.R324W on NM_001103160.2) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs751663789, COSV56115312; called by muse, mutect2, varscan2
- SIPA1L1 | c.4486T>A p.S1496T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.915); catalogued as COSV100665600; called by muse, mutect2, varscan2
- SKOR1 | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV100408397; called by muse, mutect2, varscan2
- SLC44A5 | c.785T>G p.L262R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100902121; called by muse, mutect2, varscan2
- SLITRK1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.068); catalogued as rs1196654231, COSV65675702; called by mutect2, varscan2
- SOS2 | c.2341G>T p.E781* | Nonsense Mutation (SNP) | VAF 16/162 reads (10%) | catalogued as COSV99366159; called by muse, mutect2
- SPOCD1 | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV99929944; called by muse, mutect2, varscan2
- SRD5A2 | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51873177, COSV99252408; called by muse, mutect2, varscan2
- SYT2 | c.200C>G p.A67G | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV100937142; called by muse, mutect2
- TBC1D15 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59852884; called by muse, mutect2
- TNXB | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs761408641, COSV100926377; called by muse, mutect2, varscan2
- TOP2B | c.3616G>A p.D1206N (on ENST00000264331 / NM_001330700.2; = p.D1201N on NM_001068.3) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99979765; called by muse, mutect2, varscan2
- TRAPPC9 | c.500C>G p.A167G | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV101227565; called by muse, mutect2
- TSPYL5 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.849); catalogued as COSV59070856; called by mutect2, varscan2
- UBASH3A | c.1532T>A p.I511N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99369637; called by muse, mutect2, varscan2
- UBR5 | c.7826A>T p.E2609V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99640971; called by muse, mutect2, varscan2
- UPF1 | c.790A>T p.K264* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99439649; called by muse, mutect2
- USP36 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140654133; called by muse, mutect2, varscan2
- VKORC1L1 | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100663226; called by muse, mutect2, varscan2
- XRCC4 | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982758; called by muse, mutect2, varscan2
- ZBTB7C | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV59688499; called by muse, mutect2, varscan2
- ZBTB8A | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331371; called by muse, mutect2
- ZC3H3 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771433938, COSV99367922; called by muse, mutect2, varscan2
- ZIM2 | c.826A>T p.T276S | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV99689127; called by muse, mutect2
- ZNF224 | c.305A>C p.Q102P | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100425409; called by muse, mutect2
- ZNF334 | c.1279C>T p.H427Y | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs747157309, COSV100749090; called by muse, mutect2, varscan2
- ZNF471 | c.1222T>C p.C408R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100340626; called by muse, mutect2
- CNIH1 | c.394dup p.Y132Lfs*56 | Frame Shift Ins (INS) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- DMAP1 | c.1300G>A p.D434N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.037); called by muse, mutect2
- IGHG3 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MAGEB6B | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2
- MCM8 | c.2236T>A p.Y746N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- PTTG2 | c.396_400delinsCA p.E132_R134delinsDS | In Frame Del (DEL) | VAF 54/203 reads (27%) | called by pindel, varscan2*
- ABCA10 | c.975A>T p.I325= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99288674; called by muse, mutect2
- ADGRG4 | c.6552T>C p.T2184= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99795618; called by muse, mutect2, varscan2
- BANF1 | c.207C>T p.A69= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100381385; called by muse, mutect2, varscan2
- CADM3 | c.1173C>T p.D391= (on ENST00000368125 / NM_001127173.3; = p.D425= on NM_021189.5) | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs569300786, COSV63672192; called by muse, mutect2, varscan2
- CDC7 | c.1650A>G p.L550= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV99319752; called by muse, mutect2, varscan2
- CTSC | c.1335T>G p.T445= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99910705; called by muse, mutect2, varscan2
- FAM155A | c.798G>A p.E266= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV65548528; called by muse, mutect2, varscan2
- FAT4 | c.4626G>A p.V1542= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV101272366; called by muse, mutect2, varscan2
- FCGBP | c.10974C>T p.N3658= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs140593694; called by muse, mutect2, varscan2
- FLG | c.4932G>A p.G1644= | Silent (SNP) | VAF 30/338 reads (9%) | catalogued as rs763599249, COSV100911617; called by muse, mutect2
- HGFAC | c.1230C>T p.G410= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs373005235; called by mutect2, varscan2
- HLA-G | c.474C>T p.T158= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as rs1562469676, COSV100827094; called by muse, mutect2, varscan2
- ILDR2 | c.339G>A p.L113= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV99613940; called by muse, mutect2, varscan2
- KIAA1549L | c.4566G>A p.E1522= (on ENST00000321505; = p.E1819= on NM_012194.3) | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100381651; called by muse, mutect2, varscan2
- KIF18B | c.2469C>G p.P823= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV100192215, COSV59276935; called by muse, mutect2
- LTN1 | c.4998G>A p.G1666= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as COSV63735318; called by muse, mutect2, varscan2
- MSH4 | c.2031C>A p.I677= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV54202982, COSV99591734; called by muse, mutect2, varscan2
- MYH1 | c.3069C>T p.T1023= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as rs1229716327, COSV99876046; called by muse, mutect2, varscan2
- NAV3 | c.1194C>T p.R398= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs775907789, COSV99891475; called by muse, mutect2, varscan2
- NR2F2 | c.639C>T p.C213= | Silent (SNP) | VAF 32/242 reads (13%) | catalogued as COSV101241037; called by muse, mutect2, varscan2
- NXPE3 | c.723C>T p.L241= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as COSV99839985; called by muse, mutect2
- OR5AN1 | c.360T>G p.A120= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV100004352; called by muse, mutect2, varscan2
- PCDHA12 | c.1776G>A p.A592= | Silent (SNP) | VAF 92/163 reads (56%) | catalogued as COSV56488016; called by muse, varscan2
- PSMD9 | c.570G>T p.V190= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99945671; called by muse, mutect2, varscan2
- RGS20 | c.6C>T p.P2= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV99809627; called by muse, mutect2, varscan2
- RPE65 | c.108C>T p.L36= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99254000; called by muse, mutect2, varscan2
- SACS | c.10113T>G p.T3371= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs763834751, COSV66540935; called by muse, mutect2, varscan2
- SEMA6D | c.2868T>G p.T956= (on ENST00000316364 / NM_153618.2; = p.T894= on NM_020858.2) | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV60372208; called by muse, mutect2, varscan2
- SFI1 | c.555A>G p.Q185= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs80102338, COSV101192110; called by muse, mutect2, varscan2
- SYT5 | c.582G>A p.A194= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs765589097, COSV100845909; called by muse, mutect2, varscan2
- TENM3 | c.6228C>A p.T2076= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101305152; called by muse, mutect2, varscan2
- VPS35L | c.2304G>A p.S768= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs151313380; called by muse, mutect2
- DCHS2 | n.6922A>C | RNA (SNP) | VAF 10/71 reads (14%) | catalogued as COSV100601821; called by muse, mutect2, varscan2
- FAM183BP | n.1297A>G | RNA (SNP) | VAF 50/226 reads (22%) | catalogued as rs746995709; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86033G>T | Intron (SNP) | VAF 23/125 reads (18%) | catalogued as COSV72282937; called by muse, mutect2, varscan2
- MGA | c.4435-52G>A | Intron (SNP) | VAF 13/66 reads (20%) | catalogued as rs781674279; called by muse, mutect2, varscan2
- PTGER3 | c.*24-12925C>A | Intron (SNP) | VAF 5/36 reads (14%) | catalogued as COSV63397398; called by muse, mutect2
- SUCO | chr1:172532483 T>A | 5'Flank (SNP) | VAF 3/26 reads (12%) | catalogued as COSV55270322, COSV99742904, COSV99744253; called by muse, mutect2
